Somatic mutation profile of tumor specimen 0E0846 from CCDI case PBCSLL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Angiomatoid fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 6.2 years (2,271 days).
Specimen 0E0846: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 748927c2-8b39-453a-b084-48aa943d9fa9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E084A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ed145c7-b270-4eb9-8dbb-e119d62f206b

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLHL26 | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs1316267723; called by muse, mutect2
- SETD1B | c.2392A>G p.M798V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs907702608; called by muse, mutect2
- NR1H2 | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 55/909 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- SYNE1 | c.9327G>C p.E3109D (on ENST00000367255 / NM_182961.4; = p.E3116D on NM_033071.3) | Missense Mutation (SNP) | VAF 44/1078 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2
- SLC9A9 | c.-26C>G | 5'UTR (SNP) | VAF 37/359 reads (10%) | called by muse, mutect2
